Somatic mutation profile of tumor specimen TCGA-UB-A7MD-01A (aliquot TCGA-UB-A7MD-01A-12D-A34Z-10) from TCGA case TCGA-UB-A7MD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.7 years (24,717 days).
Specimen TCGA-UB-A7MD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4387d8be-4622-4d0a-8fe4-4496c9142740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-A7MD-10A (Blood Derived Normal), aliquot TCGA-UB-A7MD-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c3d12ee-4353-4d4a-a335-cb7e0b7b8baa

The open-access MAF lists 120 somatic variants for this specimen: 93 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 26, In Frame Del 3, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- ABHD13 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65534235, COSV65535520; called by muse, mutect2, varscan2
- ACSL6 | c.547C>T p.P183S (on ENST00000379240; = p.P208S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV57293907; called by muse, mutect2, varscan2
- ADAMTS9 | c.1682C>A p.A561D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55774133, COSV55782701; called by muse, mutect2
- ADGRB2 | c.1526G>C p.G509A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57070129; called by muse, mutect2, varscan2
- ADGRG3 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59649939; called by muse, mutect2, varscan2
- AFF2 | c.1692A>T p.Q564H | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53974745; called by muse, mutect2, varscan2
- AMER1 | c.2689G>A p.D897N | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs749609920, COSV57653782; called by muse, mutect2, varscan2
- ARID1A | c.6203C>G p.S2068W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61370585, COSV61383541, COSV61384429; called by muse, mutect2, varscan2
- BNC1 | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61756382; called by muse, mutect2, varscan2
- CAD | c.4397G>T p.G1466V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53023189; called by muse, mutect2, varscan2
- CAPN9 | c.1032C>A p.D344E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV55230065; called by muse, mutect2, varscan2
- CARF | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs749820336, COSV100247759, COSV57546062; called by muse, mutect2, varscan2
- CCAR1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV56266795; called by muse, mutect2, varscan2
- CDH16 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs779352583, COSV55334558; called by muse, mutect2, varscan2
- CFAP53 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV68351222; called by muse, mutect2, varscan2
- CHURC1 | c.379A>G p.I127V (on ENST00000549115 / NM_001204063.1; = p.I128V on NM_145165.3) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1468568516, COSV63035903; called by muse, mutect2, varscan2
- COL6A3 | c.7028G>C p.R2343T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55078508, COSV55098165; called by muse, mutect2, varscan2
- COL9A1 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV61827922; called by muse, mutect2, varscan2
- DAO | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201583577; called by muse, mutect2, varscan2
- DECR2 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99557081; called by muse, mutect2
- DNAH17 | c.11920C>A p.P3974T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV67749200; called by muse, mutect2, varscan2
- DNER | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1441464155, COSV59159346; called by muse, mutect2, varscan2
- EBF1 | c.1094G>C p.R365P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58166135, COSV58177361; called by muse, mutect2, varscan2
- ECSIT | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373672064; called by muse, mutect2, varscan2
- EEA1 | c.842A>T p.Q281L | Missense Mutation (SNP) | VAF 92/325 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59282172; called by muse, mutect2, varscan2
- EEF1A1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58549515; called by muse, mutect2, varscan2
- EEF1A1 | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV58548569, COSV58549078; called by muse, mutect2, varscan2
- EPHA4 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56025682; called by muse, mutect2, varscan2
- FANCA | c.3440A>T p.D1147V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV59795261; called by muse, mutect2, varscan2
- FGR | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV64969160; called by muse, mutect2, varscan2
- FSIP2 | c.17248G>C p.E5750Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV58077311; called by muse, mutect2
- GPBAR1 | c.268T>G p.L90V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.067); catalogued as COSV50306808, COSV50309565; called by muse, mutect2, varscan2
- GPR84 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV57209186; called by muse, mutect2, varscan2
- IGHV3-53 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.606); catalogued as rs782463754; called by muse, mutect2
- IGHV3-66 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.406); catalogued as rs782270470; called by muse, mutect2, varscan2
- ITGB4 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as rs762334700, COSV52321367; called by muse, mutect2, varscan2
- KCNJ13 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as COSV52084413; called by muse, mutect2, varscan2
- KIAA1109 | c.12772A>G p.M4258V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52661200; called by muse, mutect2, varscan2
- KLHL11 | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV59861323; called by muse, mutect2, varscan2
- KMT2C | c.6023C>T p.T2008I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1280435901, COSV100069790; called by muse, varscan2
- LAMC3 | c.978C>T p.P326= | Splice Region (SNP) | VAF 10/24 reads (42%) | catalogued as COSV63088190; called by muse, mutect2, varscan2
- MELK | c.710T>G p.I237S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as COSV53196692; called by muse, mutect2, varscan2
- METTL26 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57010054; called by muse, mutect2, varscan2
- MON2 | c.4777A>T p.N1593Y | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54802428; called by muse, mutect2, varscan2
- NCBP1 | c.1788C>G p.N596K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.266); catalogued as rs200307901, COSV64307515; called by muse, mutect2, varscan2
- NLRC3 | c.1040C>A p.T347K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57086552; called by muse, mutect2, varscan2
- NPAP1 | c.2786C>A p.T929K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as COSV61503925; called by muse, mutect2, varscan2
- NPM1 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as rs1220932669, COSV51543130; called by muse, mutect2, varscan2
- OLFM1 | c.814C>T p.R272C (on ENST00000371793 / NM_001282611.2; = p.R254C on NM_014279.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747137531, COSV53276091; called by muse, mutect2, varscan2
- OR5AC2 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62279031; called by muse, mutect2, varscan2
- OR5D18 | c.454T>A p.W152R | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61736029; called by muse, mutect2, varscan2
- OR6C76 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.063); catalogued as COSV60388504; called by muse, mutect2, varscan2
- OSBPL3 | c.663A>C p.K221N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV57652032; called by muse, mutect2, varscan2
- PASD1 | c.2090C>G p.S697C | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as COSV64853885; called by muse, mutect2, varscan2
- PCDH7 | c.1774C>A p.L592M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV62336004; called by muse, mutect2, varscan2
- POLR3F | c.949T>C p.*317Qext*1 | Nonstop Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs1410277195, COSV61499665; called by muse, mutect2, varscan2
- PPP4R3B | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV55401277; called by muse, mutect2, varscan2
- PSMB5 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as rs60224002, COSV57800091; called by muse, mutect2, varscan2
- PXDN | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772042816, COSV53225554; called by muse, mutect2, varscan2
- QRICH2 | c.239A>T p.H80L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV53150376; called by muse, mutect2, varscan2
- RBFOX1 | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.121); catalogued as COSV60943474; called by muse, mutect2, varscan2
- SEMA6D | c.1856C>A p.T619K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.027); catalogued as COSV60372030; called by muse, mutect2, varscan2
- SLC1A2 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53518350; called by muse, mutect2, varscan2
- SLC1A3 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54313759; called by muse, mutect2
- SPHKAP | c.4790C>T p.P1597L (on ENST00000392056 / NM_001142644.2; = p.P1568L on NM_030623.3) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748254156, COSV60867531; called by muse, mutect2, varscan2
- SPOCK1 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs758168023, COSV56435431; called by muse, mutect2, varscan2
- SULF2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as rs201248076, COSV63413596; called by muse, mutect2, varscan2
- SUPT20H | c.805A>G p.K269E (on ENST00000350612 / NM_001014286.3; = p.K270E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV62246657; called by muse, mutect2, varscan2
- TASOR2 | c.721A>C p.S241R | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as COSV60165149; called by muse, mutect2, varscan2
- TIGD7 | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.9); catalogued as COSV51915344; called by muse, mutect2, varscan2
- TPSD1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs774535073, COSV52973706; called by muse, varscan2
- TREM1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV55147607; called by muse, mutect2, varscan2
- TRIM26 | c.905-1G>T p.X302_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV70982377; called by muse, mutect2, varscan2
- TTYH2 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV53908246; called by muse, mutect2, varscan2
- UNC45B | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.39); catalogued as COSV52091697; called by muse, mutect2, varscan2
- WDR90 | c.3154G>A p.V1052I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1462987205, COSV53465990; called by muse, mutect2, varscan2
- XIRP2 | c.618C>A p.D206E (on ENST00000628543; = p.D381E on NM_152381.6) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.526); catalogued as COSV54680205, COSV54708203; called by muse, mutect2, varscan2
- ZBTB10 | c.1682A>G p.N561S | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV66946266; called by muse, mutect2, varscan2
- ZDBF2 | c.5495G>A p.W1832* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV65621348; called by muse, mutect2, varscan2
- ZNF267 | c.1593T>G p.C531W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.369); catalogued as COSV56250228; called by muse, mutect2, varscan2
- ZNF335 | c.1389G>T p.R463S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59815769; called by muse, mutect2, varscan2
- ZNF436 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV58357922; called by muse, mutect2, varscan2
- ARHGAP45 | c.2899_2901del p.I967del | In Frame Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- C3 | c.4336_4338del p.I1446del | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- CYP4F2 | c.152del p.F51Sfs*24 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- GSK3B | c.687T>G p.F229L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCFC2 | c.763_764del p.N255Qfs*12 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by mutect2, varscan2
- SLC44A3 | c.1638_1646del p.T547_F549del (on ENST00000271227 / NM_001114106.3; = p.T499_F501del on NM_152369.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 63/243 reads (26%) | called by mutect2, pindel, varscan2
- SREBF1 | c.1372del p.E458Sfs*240 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.1799_1800insTAAT p.L601Nfs*8 | Frame Shift Ins (INS) | VAF 24/125 reads (19%) | called by mutect2, pindel, varscan2
- ACOT9 | c.597A>G p.A199= | Silent (SNP) | VAF 120/176 reads (68%) | catalogued as COSV60536815; called by muse, mutect2, varscan2
- ANKRD10 | c.864C>G p.S288= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV57442512, COSV99941333; called by muse, mutect2, varscan2
- CFAP221 | c.1587G>A p.S529= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs202085071; called by muse, mutect2, varscan2
- CHST9 | c.984C>T p.V328= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV52428606, COSV52429192; called by muse, mutect2, varscan2
- DNAH8 | c.3468A>G p.E1156= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs368262519; called by muse, mutect2, varscan2
- DVL2 | c.114C>T p.I38= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1319899061, COSV50034522; called by muse, mutect2, varscan2
- ELOA2 | c.1503T>A p.A501= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV55292686; called by muse, mutect2, varscan2
- EME2 | c.1119C>T p.L373= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs767527361, COSV51598745; called by muse, mutect2, varscan2
- FASLG | c.402C>T p.P134= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as rs143306673; called by muse, mutect2, varscan2
- GAL | c.195G>A p.E65= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV55763429; called by muse, mutect2, varscan2
- IGF2R | c.1189A>C p.R397= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV63626039; called by muse, mutect2, varscan2
- KMT2C | c.6024T>A p.T2008= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs369706450; called by muse, varscan2
- LRRC6 | c.867G>A p.R289= | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as COSV51537346; called by muse, mutect2, varscan2
- MDN1 | c.4365G>C p.L1455= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV65516416; called by muse, mutect2, varscan2
- PCDHA1 | c.2016C>T p.S672= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs540450492, COSV65372430, COSV65377285; called by muse, mutect2, varscan2
- PDE8A | c.1896G>A p.L632= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV59634494; called by muse, mutect2, varscan2
- PEG3 | c.4158G>A p.R1386= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55623569; called by muse, mutect2, varscan2
- PLA2G4E | c.1758G>T p.L586= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV68148599; called by muse, mutect2, varscan2
- PRAME | c.585C>T p.L195= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV67160865; called by muse, mutect2, varscan2
- SPTBN5 | c.1059C>T p.T353= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV58015790; called by muse, mutect2, varscan2
- STEAP4 | c.1044T>C p.Y348= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100112396, COSV57327827; called by muse, mutect2, varscan2
- UBAC1 | c.660G>T p.S220= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV65613621; called by muse, mutect2, varscan2
- UBE2Z | c.324C>T p.I108= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV62875129; called by muse, mutect2, varscan2
- XIRP2 | c.8331A>G p.E2777= (on ENST00000628543; = p.E2952= on NM_152381.6) | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV54680226; called by muse, mutect2, varscan2
- ZNF28 | c.624A>T p.V208= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV60421545; called by muse, mutect2, varscan2
- ZNF415 | c.873G>A p.R291= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54698813; called by muse, mutect2, varscan2
- CDH11 | c.1895-612A>G | Intron (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99217824; called by muse, mutect2, varscan2
